Somatic mutation profile of tumor specimen 0DDVT4 from CCDI case PBBNVU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,558 days).
Specimen 0DDVT4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 206f11ad-699e-4e2d-b8c4-81d9bd99362c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDVT5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bda659d-9de7-44ad-a1fb-bb4299b0649b

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX3X | c.1597C>T p.R533C (on ENST00000399959; = p.R534C on NM_001356.5) | Missense Mutation (SNP) | VAF 392/669 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1555954284, COSV67863588, COSV67863748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFL8 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 244/623 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs146391240; called by muse, mutect2, varscan2
- GNAS | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 600/1329 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55672532; called by muse, mutect2, varscan2
- LZTS2 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 302/712 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as rs748860681; called by muse, mutect2, varscan2
- REP15 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 409/943 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756585296; called by muse, mutect2, varscan2
- RPTOR | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 380/1131 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as rs377507180; called by muse, mutect2, varscan2
- TTC38 | c.1382A>T p.K461M | Missense Mutation (SNP) | VAF 363/745 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1409945525; called by muse, mutect2, varscan2
- ZER1 | c.1498G>A p.V500M | Missense Mutation (SNP) | VAF 207/702 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768832521, COSV52565735; called by muse, mutect2, varscan2
- ZNF521 | c.3485G>C p.R1162P | Missense Mutation (SNP) | VAF 389/870 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs146072050; called by muse, mutect2, varscan2
- DDX3X | c.1242C>G p.I414M (on ENST00000399959; = p.I415M on NM_001356.5) | Missense Mutation (SNP) | VAF 40/789 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- DEFB119 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 31/1207 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.305); called by muse, mutect2
- GNAS | c.21_22del p.S7Rfs*14 | Frame Shift Del (DEL) | VAF 142/402 reads (35%) | called by mutect2, pindel, varscan2
- OTX1 | c.225del p.N76Tfs*82 | Frame Shift Del (DEL) | VAF 546/1419 reads (38%) | called by mutect2, pindel, varscan2
- SLCO6A1 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 340/733 reads (46%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAG3 | c.3427G>A p.G1143S | Missense Mutation (SNP) | VAF 31/846 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.042); called by muse, mutect2
- FTMT | c.678G>A p.A226= | Silent (SNP) | VAF 409/918 reads (45%) | catalogued as rs755705590, COSV58421431; called by muse, mutect2, varscan2
- GPR137 | c.597G>A p.R199= | Silent (SNP) | VAF 456/991 reads (46%) | called by muse, mutect2, varscan2
- TMEM30A | c.249C>T p.T83= | Silent (SNP) | VAF 359/910 reads (39%) | catalogued as rs775152351, COSV57876971; called by muse, mutect2, varscan2
- WDHD1 | c.531A>G p.L177= | Silent (SNP) | VAF 31/1247 reads (2%) | catalogued as rs1393808699; called by muse, mutect2
- TMEM273 | c.269+532C>T | Intron (SNP) | VAF 411/1011 reads (41%) | called by muse, mutect2, varscan2
